Somatic mutation profile of tumor specimen TCGA-FP-A9TM-01A (aliquot TCGA-FP-A9TM-01A-11D-A397-08) from TCGA case TCGA-FP-A9TM, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G2; Age at diagnosis: 77.7 years (28,376 days).
Specimen TCGA-FP-A9TM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27b45c7e-a8c1-4f7d-9732-7a6ad430cb92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-A9TM-10A (Blood Derived Normal), aliquot TCGA-FP-A9TM-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa4ccd0b-1ced-40b2-a399-822f2f179ec2

The open-access MAF lists 162 somatic variants for this specimen: 120 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 37, Nonsense Mutation 7, Splice Region 3, Frame Shift Del 3, Splice Site 3, Intron 2, Translation Start Site 1, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMNA | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs60864230, CM012998, CM032006, COSV100738901; ClinVar: pathogenic / not provided; called by muse, varscan2
- NR2F1 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs1297603674, COSV59067720; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ACTL7A | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs779105077, COSV61776334; called by muse, mutect2, varscan2
- ADAMTS9 | c.2923G>T p.V975F | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99900385; called by muse, mutect2, varscan2
- AKAP9 | c.11444C>T p.S3815F (on ENST00000359028; = p.S3791F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV100663314; called by muse, mutect2, varscan2
- ARSI | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs1217868286; called by muse, mutect2
- ASXL1 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100041662; called by muse, mutect2, varscan2
- ATP13A1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs776945337, COSV99366697; called by muse, mutect2, varscan2
- BEX3 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100244381; called by muse, mutect2, varscan2
- CACNA2D4 | c.1809G>A p.L603= | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as COSV54950092; called by muse, mutect2, varscan2
- CCR3 | c.659C>A p.T220K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100656815; called by muse, mutect2
- CDH9 | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as rs764882241, COSV50263738; called by muse, mutect2, varscan2
- CEP131 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.744); catalogued as rs376964153, COSV99488672; called by muse, mutect2, varscan2
- CFAP61 | c.2775G>T p.K925N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV99846964; called by muse, mutect2
- CLSTN3 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs575113186, COSV99866797; called by muse, varscan2
- COL1A2 | c.2784C>A p.G928= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as rs1483107061, COSV51952432, COSV99801432; called by muse, mutect2, varscan2
- COL4A6 | c.3476C>T p.P1159L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV100565174; called by muse, mutect2, varscan2
- CYLC1 | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100255626; called by muse, mutect2, varscan2
- DCHS1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs764551786, COSV55037496; called by muse, mutect2, varscan2
- DCSTAMP | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99887086; called by muse, mutect2, varscan2
- DNAJB6 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV51095674; called by muse, mutect2
- DNM1L | c.1366C>G p.R456G | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV104383704, COSV99846543; called by muse, mutect2, varscan2
- DPP10 | c.161T>A p.I54N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100072890; called by muse, mutect2
- DYNC1H1 | c.6421G>A p.V2141I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as rs765613848, COSV64137265, COSV64137462; ClinVar: uncertain significance; called by muse, mutect2
- ELAPOR1 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1434062423, COSV100884784; called by muse, mutect2
- EMILIN2 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV99599027; called by muse, mutect2, varscan2
- ENTPD4 | c.557C>G p.P186R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768345832, COSV62269780; called by muse, mutect2, varscan2
- EPHA3 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV60721623; called by muse, mutect2, varscan2
- ERICH3 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100446064, COSV58606942; called by muse, mutect2
- ETFDH | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772351035, COSV100307026; called by muse, mutect2, varscan2
- FAM107B | c.283G>A p.E95K (on ENST00000378458 / NM_001320737.1; = p.E270K on NM_031453.3) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99474607; called by muse, mutect2, varscan2
- FAM170A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs775441770, COSV58926608; called by muse, mutect2, varscan2
- FANCA | c.792+2T>C p.X264_splice | Splice Site (SNP) | VAF 23/124 reads (19%) | catalogued as COSV101225304; called by muse, mutect2, varscan2
- FLRT2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766170020, COSV100420725, COSV58149961; called by muse, mutect2, varscan2
- GBA3 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV72437990; called by muse, mutect2
- GET4 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs754748449, COSV99768324; called by muse, mutect2, varscan2
- GPR156 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV100251777; called by muse, mutect2, varscan2
- GPR37 | c.541T>A p.Y181N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV58259789; called by muse, mutect2
- GREB1 | c.4047C>T p.I1349= | Splice Region (SNP) | VAF 13/84 reads (15%) | catalogued as rs781383668, COSV52184405; called by muse, mutect2, varscan2
- GRM7 | c.1101C>A p.Y367* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100739207; called by muse, mutect2, varscan2
- GUCA2B | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.754); catalogued as rs544541287, COSV65367948; called by muse, mutect2, varscan2
- HHIPL2 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1470194447, COSV100597160; called by muse, mutect2
- HNRNPM | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs759532478, COSV55312794; called by muse, mutect2, varscan2
- HTR7 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53292948; called by muse, mutect2, varscan2
- KCNC1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789835; called by muse, mutect2, varscan2
- KCNH1 | c.2395T>C p.S799P (on ENST00000271751 / NM_172362.3; = p.S772P on NM_002238.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99661954; called by muse, mutect2, varscan2
- KIAA0408 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs1262456328, COSV100847106; called by muse, mutect2, varscan2
- KIF1A | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747643976, COSV57487522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNTC1 | c.3444A>C p.L1148F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV100338907; called by muse, varscan2
- LBP | c.1117T>A p.S373T | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV99461435; called by muse, mutect2
- LBX2 | c.551A>C p.D184A (on ENST00000377566 / NM_001282430.2; = p.D180A on NM_001009812.2) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1461440313, COSV99282428; called by muse, mutect2, varscan2
- LRFN3 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373172486; called by muse, mutect2, varscan2
- LRP1B | c.4677G>C p.L1559F | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101262116; called by muse, mutect2, varscan2
- LRRIQ3 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1253984416, COSV100599582; called by muse, mutect2, varscan2
- LYZL2 | c.209G>A p.R70H (on ENST00000375318; = p.R24H on NM_183058.3) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs375255325, COSV100940618; called by muse, mutect2, varscan2
- MAGI2 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62640251; called by muse, mutect2, varscan2
- MAP1B | c.3448G>A p.E1150K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.411); catalogued as COSV99703034; called by muse, mutect2, varscan2
- MNT | c.775A>C p.S259R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99438405; called by muse, mutect2, varscan2
- MUC16 | c.32680C>A p.P10894T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.112); catalogued as COSV101202086, COSV67498739; called by muse, mutect2, varscan2
- MUC16 | c.30166C>T p.P10056S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.014); catalogued as COSV101202087; called by muse, mutect2, varscan2
- MYT1L | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.971); catalogued as COSV101221560; called by muse, mutect2, varscan2
- NFX1 | c.1121G>T p.C374F | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100582528; called by muse, mutect2, varscan2
- NR6A1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV100748727; called by muse, mutect2
- OR11L1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1387836253, COSV100869507; called by muse, mutect2, varscan2
- OR4C15 | c.244G>T p.V82L (on ENST00000314644; = p.V28L on NM_001001920.2) | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.065); catalogued as rs1364452843, COSV100116182, COSV58956392; called by muse, mutect2
- OR4F6 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 20/280 reads (7%) | catalogued as rs775466060, COSV100187024, COSV61027475; called by muse, mutect2
- OR4X1 | c.678C>A p.H226Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100186685, COSV60724014; called by muse, mutect2, varscan2
- OSBPL8 | c.2555G>A p.R852Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.043); catalogued as rs191644576, COSV53881081; called by muse, mutect2, varscan2
- PAPPA2 | c.4898G>T p.C1633F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100868798; called by muse, varscan2
- PCDHA4 | c.2277C>G p.C759W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV100793831; called by muse, mutect2, varscan2
- PDIA3 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV100295379; called by muse, mutect2, varscan2
- PIK3CG | c.2287+1G>T p.X763_splice | Splice Site (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100783267; called by muse, mutect2
- PPP4R1 | c.1957G>A p.A653T (on ENST00000400556 / NM_001042388.3; = p.A636T on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1220882697, COSV99554074; called by muse, mutect2, varscan2
- PREX1 | c.2992C>T p.R998C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1183001582, COSV100906893; called by muse, mutect2
- PRKCD | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as rs1477567912, COSV100388166; called by muse, mutect2
- PSG3 | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs772450674, COSV100549348; called by muse, mutect2, varscan2
- RASAL3 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV100640347; called by muse, mutect2, varscan2
- RESF1 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV100440694; called by muse, mutect2, varscan2
- RHOBTB2 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs371598054; called by muse, mutect2, varscan2
- SBF1 | c.4465C>T p.R1489C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs748910673, COSV100818097; called by muse, mutect2, varscan2
- SCN2A | c.2747A>G p.N916S | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs763684457, COSV99333935; called by muse, mutect2, varscan2
- SCN9A | c.5185G>T p.D1729Y (on ENST00000303354; = p.D1718Y on NM_002977.3) | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100314545; called by muse, mutect2, varscan2
- SCUBE2 | c.2620C>T p.R874C (on ENST00000649792 / NM_001367977.2; = p.R817C on NM_020974.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289340109, COSV58548458; called by muse, mutect2, varscan2
- SCYL3 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.696); catalogued as COSV100884329; called by muse, mutect2, varscan2
- SEC23A | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs778291254, COSV56973645; called by muse, mutect2
- SERPINA10 | c.465C>A p.N155K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56228325; called by muse, mutect2, varscan2
- SERPINE1 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201327802, COSV56168926; called by muse, mutect2, varscan2
- SHLD1 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.958); catalogued as COSV100290762; called by muse, mutect2, varscan2
- SIAE | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV99704236; called by muse, mutect2
- SLC17A4 | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV99766229; called by muse, mutect2, varscan2
- SLC4A2 | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs139758611; called by muse, mutect2, varscan2
- SLCO4C1 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1165732807, COSV60512796; called by muse, mutect2, varscan2
- TAF1L | c.4459C>T p.Q1487* | Nonsense Mutation (SNP) | VAF 68/220 reads (31%) | catalogued as COSV99645596; called by muse, mutect2, varscan2
- TBC1D9B | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.334); catalogued as COSV100783689, COSV62282488; called by muse, mutect2, varscan2
- TCHHL1 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100916637; called by muse, mutect2, varscan2
- TGM5 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55013095; called by muse, mutect2
- TRAPPC3 | c.287G>A p.W96* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100920373; called by muse, mutect2, varscan2
- TRIM41 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV59317282; called by muse, mutect2
- TRPA1 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs573631197, COSV100085472; called by muse, mutect2, varscan2
- TXNRD1 | c.1183A>T p.I395F (on ENST00000525566 / NM_001093771.3; = p.I297F on NM_003330.4) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100723611; called by muse, mutect2
- UBA3 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734797; called by muse, mutect2
- WDR72 | c.1879A>C p.K627Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV100855217; called by muse, mutect2, varscan2
- WDR75 | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV100134508; called by muse, mutect2
- WDR81 | c.4786G>A p.G1596R (on ENST00000409644 / NM_001163809.2; = p.G545R on NM_152348.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs148122027; called by muse, mutect2
- ZEB2 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100357147; called by muse, mutect2
- ZNF222 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV99496670; called by muse, mutect2, varscan2
- ZNF331 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs1439866997, COSV99468150; called by muse, mutect2
- ZNF397 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99735221; called by muse, mutect2, varscan2
- ZNF516 | c.2768G>A p.G923E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV101487384; called by muse, mutect2, varscan2
- ZNF549 | c.207G>T p.L69F (on ENST00000376233 / NM_001199295.2; = p.L56F on NM_153263.2) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1232696450, COSV99558842; called by muse, mutect2, varscan2
- ZNF611 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100160698; called by muse, mutect2, varscan2
- ZNF793 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101495718; called by muse, mutect2, varscan2
- DSG3 | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.028); called by muse, mutect2
- KLHL6 | c.583_584del p.S195Lfs*13 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | called by pindel, varscan2
- KMT2C | c.5088del p.A1697Pfs*20 | Frame Shift Del (DEL) | VAF 36/308 reads (12%) | called by mutect2, pindel, varscan2
- NOVA1 | c.255_258del p.K87Pfs*14 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | called by mutect2, pindel
- PDZRN4 | c.850G>T p.G284W (on ENST00000402685 / NM_001164595.2; = p.G26W on NM_013377.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- UGT2A1 | c.1304+1_1304+16del p.X435_splice | Splice Site (DEL) | VAF 34/111 reads (31%) | called by mutect2, pindel, varscan2
- ZFP64 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.254); called by muse, mutect2
- ACAN | c.657C>T p.G219= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100719429, COSV61365606; called by muse, mutect2, varscan2
- APCDD1L | c.360G>A p.R120= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100954116, COSV100954134; called by muse, mutect2
- ARHGEF17 | c.2889C>T p.P963= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs753577516, COSV99735098; called by muse, mutect2, varscan2
- ATCAY | c.369C>T p.P123= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs192528603, COSV100009092; called by muse, mutect2, varscan2
- BRINP3 | c.1380C>T p.C460= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1348043617, COSV66526179; called by muse, mutect2, varscan2
- DNAH10 | c.5523G>A p.P1841= (on ENST00000409039; = p.P1780= on NM_207437.3) | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs376267774; called by muse, mutect2, varscan2
- DNAH9 | c.4359C>T p.P1453= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1255706253, COSV99308724; called by muse, mutect2, varscan2
- DNAJB4 | c.882T>C p.I294= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100883511; called by muse, mutect2, varscan2
- EIF5AL1 | c.159C>T p.H53= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1379612668, COSV101592809; called by mutect2, varscan2
- EXO1 | c.444C>T p.P148= | Silent (SNP) | VAF 7/152 reads (5%) | catalogued as rs1410324424; called by muse, mutect2
- EXOC7 | c.663G>A p.Q221= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100135813, COSV100135896; called by muse, mutect2, varscan2
- FMO2 | c.1356C>T p.L452= | Silent (SNP) | VAF 11/238 reads (5%) | catalogued as COSV99269382; called by muse, mutect2
- GAB3 | c.444C>G p.T148= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100850721; called by muse, mutect2, varscan2
- GREB1 | c.3783G>A p.L1261= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs746895191, COSV99304003; called by muse, varscan2
- GUK1 | c.339C>T p.T113= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs772433405, COSV57158432; called by muse, mutect2, varscan2
- HEBP2 | c.450G>A p.K150= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100874962, COSV62928454; called by muse, mutect2, varscan2
- HEPH | c.2607C>T p.G869= (on ENST00000343002; = p.G602= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100293889; called by muse, mutect2, varscan2
- HRH2 | c.996C>A p.P332= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV99200072; called by muse, mutect2, varscan2
- KIAA1217 | c.1968C>T p.L656= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100287437; called by muse, mutect2, varscan2
- KLHL25 | c.1260G>A p.G420= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100563765; called by muse, mutect2
- KLK14 | c.324C>T p.H108= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs368388935; called by muse, varscan2
- KRT31 | c.399C>T p.N133= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs538647973, COSV52435279, COSV99289372; called by muse, mutect2, varscan2
- KRT71 | c.99G>A p.R33= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99922444; called by muse, mutect2, varscan2
- LMNA | c.471G>T p.T157= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs150645079, CM121337, COSV100738904; called by muse, varscan2
- ME3 | c.1266G>A p.T422= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs749644334, COSV100661162; called by muse, mutect2, varscan2
- NCF4 | c.810G>T p.L270= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99957592; called by muse, mutect2
- NEIL3 | c.306C>T p.I102= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV99221009; called by muse, mutect2
- NGLY1 | c.516A>G p.L172= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1375458103, COSV99770996; called by muse, varscan2
- PDCD11 | c.4488C>T p.D1496= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs368345049; called by muse, mutect2, varscan2
- SRRM2 | c.5964G>A p.P1988= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs776779115, COSV99241776; called by muse, mutect2, varscan2
- SUCLG2 | c.480G>T p.R160= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV100215026, COSV56210808; called by muse, mutect2
- WNT8A | c.1047C>A p.G349= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs1263163369, COSV100843112; called by muse, mutect2, varscan2
- ZIC1 | c.1002C>T p.C334= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV51554806, COSV99292567; called by muse, mutect2
- ZNF318 | c.4287A>G p.E1429= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs1356511680, COSV100546579; called by muse, mutect2, varscan2
- ZNF324B | c.1290C>T p.C430= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs767355218, COSV100351836; called by muse, mutect2, varscan2
- ZNF512B | c.1224G>A p.A408= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs369782708; called by muse, mutect2, varscan2
- ZNF518A | c.1383G>A p.V461= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100283784; called by muse, mutect2, varscan2
- COL6A2 | c.2461+2682C>T | Intron (SNP) | VAF 7/68 reads (10%) | catalogued as rs369164026, COSV100154471, COSV56013171; called by muse, mutect2, varscan2
- IFNG | c.-2C>T | 5'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs886049802, COSV99971326; called by muse, mutect2
- MAGI1 | chr3:66038309 G>A | 5'Flank (SNP) | VAF 9/53 reads (17%) | catalogued as rs1201099013, COSV100443408; called by muse, mutect2, varscan2
- RAB6A | c.184-130C>T | Intron (SNP) | VAF 35/105 reads (33%) | catalogued as rs1162494305, COSV100155231; called by muse, mutect2, varscan2
- SNORD116-12 | n.7A>T | RNA (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
